Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1BI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1BI-01B (Primary Tumor).

SURGICAL PATHOLOGY REPORT - CONSULT

Service: Inside/Outside
Location: [REDACTED]
MRN: [REDACTED]
Hospital #: [REDACTED]
Patient Type: [REDACTED]

Accession #: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

DIAGNOSIS

UTERINE ENDOCERVIX CURETTAGE (OSC [REDACTED] 1A, 1B, AND 1C [REDACTED])
INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED (SEE COMMENT)

UTERUS, ENDOMETRIUM, CURETTAGE (OSC [REDACTED] 2A AND 2B [REDACTED])
INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED
NO ENDOMETRIAL EPITHELIUM IDENTIFIED

By this statement, I affirm that the above diagnosis is based upon my personal examination of the slides and/or other material deposited in the diagnostic laboratory.

Report Electronically Reviewed and Signed Out [REDACTED]

Microscopic Description and Comment

The endocervical curettage contains abundant fragments of moderately differentiated squamous cell carcinoma. Although normal invasion is widespread, the depth of invasion cannot be determined, and there is no definitive lymphovascular space invasion. Fragments of benign squamous and endocervical epithelium are also present. The endometrial curettage contains a moderate amount of the same tumor. No normal epithelium is identified. (OSC [REDACTED] T-05 [REDACTED])

History

The patient is a [REDACTED] year old woman with heavy vaginal bleeding and a history of usage of an intrauterine device.

Material(s) Received

Received are five slides labeled [REDACTED] accompanied by a corresponding pathology report dated [REDACTED]. The material originates from [REDACTED]

Source: NCI Genomic Data Commons file f3141524-1e71-49d6-8f2e-9217b0c03b61 (TCGA-C5-A1BI.25B6B201-ECCC-44F5-82AF-B9DC7848A117.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).